Somatic mutation profile of tumor specimen MMRF_1462_4_BM_CD138pos (aliquot MMRF_1462_4_BM_CD138pos_T1_KHS5U_L13763) from MMRF case MMRF_1462, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.6 years (21,779 days).
Specimen MMRF_1462_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18bc00d1-e1ee-45a8-9e68-607431574fe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1462_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1462_1_PB_Whole_C3_KAS5U_L02464; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04794e3b-6bf4-4616-a5e7-f4b099b7e363

The open-access MAF lists 120 somatic variants for this specimen: 54 protein-altering or splice-affecting, 20 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 24, Silent 20, Intron 11, 5'UTR 6, Nonsense Mutation 5, Splice Site 2, 3'Flank 2, Frame Shift Del 2, 5'Flank 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 91/137 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAMP | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1248958261, COSV50307674; called by muse, mutect2, varscan2
- ARG1 | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.139); catalogued as COSV51581477; called by muse, mutect2, varscan2
- ASNSD1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 199/451 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99641119; called by muse, mutect2, varscan2
- ATE1 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 108/200 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs960328457; called by muse, mutect2, varscan2
- COL20A1 | c.3026C>T p.T1009M | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200056990, COSV100491036; called by muse, mutect2, varscan2
- DNAH2 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs140417225; called by muse, mutect2, varscan2
- DSE | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1486246312; called by muse, mutect2, varscan2
- FAM71E2 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs771386874; called by muse, mutect2, varscan2
- IGKV4-1 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 74/74 reads (100%) | catalogued as rs778196241; called by muse, varscan2
- IGKV5-2 | c.55A>G p.R19G | Missense Mutation (SNP) | VAF 139/142 reads (98%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760745682; called by muse, mutect2, varscan2
- IGKV5-2 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 159/165 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs761508612; called by muse, mutect2, varscan2
- MARCHF3 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 150/251 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs760059259; called by muse, mutect2, varscan2
- MYO18A | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 114/221 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as rs887114321; called by muse, mutect2, varscan2
- NAXD | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 195/210 reads (93%) | catalogued as rs921496694, COSV57289297; called by muse, mutect2, varscan2
- PGBD5 | c.734C>T p.A245V (on ENST00000525115; = p.A314V on NM_001258311.2) | Missense Mutation (SNP) | VAF 206/341 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs1488372662, COSV58413566; called by muse, mutect2, varscan2
- PPP1CA | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs771504128; called by muse, mutect2, varscan2
- PRRC2A | c.5560G>A p.D1854N | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as rs1207990295; called by muse, mutect2
- UBQLN3 | c.1654A>T p.T552S | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs751495844; called by muse, mutect2, varscan2
- ZNF142 | c.4631G>A p.R1544Q (on ENST00000411696 / NM_001379660.1; = p.R1344Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs374554076; called by muse, mutect2, varscan2
- ZNF43 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.795); catalogued as COSV61685227; called by muse, mutect2, varscan2
- ACTG1 | c.101_115del p.I34_P38del | In Frame Del (DEL) | VAF 144/382 reads (38%) | called by mutect2, pindel, varscan2
- ANKRD16 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CFAP46 | c.4341C>G p.N1447K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFH | c.3137C>A p.T1046N | Missense Mutation (SNP) | VAF 270/432 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CIT | c.4586C>G p.S1529C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- COPA | c.283T>G p.Y95D | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ10A | c.44_65del p.A15Gfs*23 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, varscan2
- CRYGD | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- DDIT4 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAI4 | c.530+2T>G p.X177_splice | Splice Site (SNP) | VAF 43/48 reads (90%) | called by muse, mutect2, varscan2
- FBXL12 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GADD45A | c.146+2T>A p.X49_splice | Splice Site (SNP) | VAF 35/40 reads (88%) | called by muse, mutect2, varscan2
- GPR158 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELZ | c.3544C>T p.Q1182* | Nonsense Mutation (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 92/170 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, varscan2
- IGHV2-70D | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, varscan2
- KHDRBS1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 65/239 reads (27%) | called by muse, mutect2, varscan2
- N4BP2 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NLN | c.1414C>G p.L472V | Missense Mutation (SNP) | VAF 89/141 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NUMA1 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR1S2 | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.146); called by muse, mutect2
- PRRC2A | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- PSG11 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAD21L1 | c.1486T>A p.S496T | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RB1CC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 95/174 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SGIP1 | c.1556C>A p.T519N | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC35G2 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 216/465 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYDE1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TSHZ1 | c.1330G>T p.V444L (on ENST00000580243 / NM_001308210.2; = p.V399L on NM_005786.6) | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- TTN | c.17105A>C p.Q5702P (on ENST00000591111; = p.Q4775P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/164 reads (47%) | PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZNF142 | c.4199_4209del p.H1400Lfs*3 (on ENST00000411696 / NM_001379660.1; = p.H1200Lfs*3 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | called by mutect2, pindel, varscan2
- ZNF727 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 71/164 reads (43%) | called by muse, mutect2, varscan2
- ZNF865 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC62 | c.1446G>C p.L482= | Silent (SNP) | VAF 70/109 reads (64%) | called by muse, mutect2, varscan2
- CEP250 | c.721C>A p.R241= | Silent (SNP) | VAF 112/220 reads (51%) | called by muse, mutect2, varscan2
- DDIT4 | c.369G>A p.L123= | Silent (SNP) | VAF 71/149 reads (48%) | catalogued as rs1564804769; called by muse, mutect2, varscan2
- DISP3 | c.1639C>T p.L547= | Silent (SNP) | VAF 210/311 reads (68%) | catalogued as COSV53822452; called by muse, mutect2, varscan2
- ESYT3 | c.255C>T p.A85= | Silent (SNP) | VAF 84/202 reads (42%) | called by muse, mutect2, varscan2
- FREM2 | c.6990G>A p.V2330= | Silent (SNP) | VAF 107/114 reads (94%) | called by muse, mutect2, varscan2
- HSPA8 | c.441A>C p.P147= | Silent (SNP) | VAF 61/115 reads (53%) | called by muse, mutect2, varscan2
- IGLL5 | c.153C>T p.D51= | Silent (SNP) | VAF 28/30 reads (93%) | catalogued as rs759339896, COSV104440311, COSV73249815; called by muse, varscan2
- KHDRBS1 | c.561G>C p.L187= | Silent (SNP) | VAF 63/236 reads (27%) | called by muse, mutect2, varscan2
- MMP2 | c.345C>T p.R115= | Silent (SNP) | VAF 83/151 reads (55%) | called by muse, mutect2, varscan2
- NYAP1 | c.750C>T p.A250= | Silent (SNP) | VAF 112/234 reads (48%) | catalogued as rs147915491; called by muse, mutect2, varscan2
- OCA2 | c.786C>T p.S262= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV62353397; called by muse, mutect2, varscan2
- PCDHA3 | c.1929G>A p.P643= | Silent (SNP) | VAF 15/234 reads (6%) | catalogued as rs924510716; called by muse, mutect2
- PHF12 | c.2067C>T p.F689= | Silent (SNP) | VAF 124/238 reads (52%) | called by muse, mutect2, varscan2
- PUM1 | c.3207A>C p.V1069= | Silent (SNP) | VAF 193/309 reads (62%) | called by muse, mutect2, varscan2
- PUM1 | c.3111A>G p.V1037= | Silent (SNP) | VAF 74/107 reads (69%) | called by muse, mutect2, varscan2
- SNAPC4 | c.2535C>G p.L845= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV53738858; called by muse, mutect2
- TOPORS | c.1815G>A p.Q605= | Silent (SNP) | VAF 190/450 reads (42%) | called by muse, mutect2, varscan2
- UMAD1 | c.15C>T p.F5= | Silent (SNP) | VAF 114/227 reads (50%) | called by muse, mutect2, varscan2
- ZNF142 | c.3786C>A p.P1262= (on ENST00000411696 / NM_001379660.1; = p.P1062= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 72/156 reads (46%) | called by muse, mutect2, varscan2
- ABHD13 | c.*3876G>A | 3'UTR (SNP) | VAF 19/21 reads (90%) | called by muse, mutect2, varscan2
- ARL5B | c.*2893A>T | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- BOLL | c.-16+235G>T | Intron (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- CDKN2AIP | c.403+151C>A | Intron (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
- COL3A1 | c.*220T>C | 3'UTR (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- CYSLTR2 | c.*851G>T | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- DIO3OS | chr14:101552578 G>A | 3'Flank (SNP) | VAF 61/64 reads (95%) | called by muse, mutect2, varscan2
- EIF3H | c.*431C>A | 3'UTR (SNP) | VAF 29/52 reads (56%) | catalogued as rs1164480684; called by muse, mutect2, varscan2
- ELP1 | c.741-16_741-11del | Intron (DEL) | VAF 80/181 reads (44%) | called by mutect2, pindel, varscan2
- FAM76B | c.*1297T>G | 3'UTR (SNP) | VAF 38/68 reads (56%) | called by muse, mutect2, varscan2
- IRAG1 | c.*1917T>C | 3'UTR (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- MBOAT2 | c.*2231C>T | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- MEOX2 | c.*1158A>T | 3'UTR (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- MEOX2 | c.*1036T>C | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851175 T>C | 5'Flank (SNP) | VAF 146/301 reads (49%) | catalogued as rs529449665; called by muse, mutect2, varscan2
- MORC2 | c.68+82T>A | Intron (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- MPIG6B | c.622-31C>A | Intron (SNP) | VAF 145/322 reads (45%) | called by muse, mutect2, varscan2
- MSRB3 | c.*2899A>T | 3'UTR (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- NAALADL2 | c.-4T>G | 5'UTR (SNP) | VAF 195/404 reads (48%) | called by muse, mutect2, varscan2
- NCBP2 | c.*580G>C | 3'UTR (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- NFASC | c.*3140A>T | 3'UTR (SNP) | VAF 142/226 reads (63%) | called by muse, mutect2, varscan2
- OR10Z1 | chr1:158610450 T>C | 3'Flank (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2
- OR51E1 | c.*508G>C | 3'UTR (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- PDGFC | c.*454T>A | 3'UTR (SNP) | VAF 46/76 reads (61%) | called by muse, mutect2, varscan2
- PHKB | c.*1751A>G | 3'UTR (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- PIGG | c.-74G>A | 5'UTR (SNP) | VAF 38/40 reads (95%) | called by muse, mutect2, varscan2
- PLA2G4C | c.1006+135T>C | Intron (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- POLD4 | c.-91T>C | 5'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- PRLR | c.*5757C>T | 3'UTR (SNP) | VAF 44/81 reads (54%) | called by muse, mutect2, varscan2
- PRRC1 | c.*1875C>T | 3'UTR (SNP) | VAF 7/184 reads (4%) | catalogued as rs951612612; called by muse, mutect2
- RNF144A | c.*3462G>C | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- ROBO2 | c.-618G>T | 5'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- SAG | c.806+137C>T | Intron (SNP) | VAF 19/41 reads (46%) | catalogued as rs573374394; called by muse, mutect2, varscan2
- SEMA3D | c.*2934T>C | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- SINHCAF | c.-21+2056G>A | Intron (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- SIX4 | c.*1582A>C | 3'UTR (SNP) | VAF 13/15 reads (87%) | called by muse, mutect2, varscan2
- SLC24A1 | c.2883+58C>T | Intron (SNP) | VAF 121/239 reads (51%) | called by muse, mutect2, varscan2
- SMAD7 | c.*487C>T | 3'UTR (SNP) | VAF 61/115 reads (53%) | catalogued as rs945462191; called by muse, mutect2, varscan2
- SRPK2 | c.71+82084A>T | Intron (SNP) | VAF 96/205 reads (47%) | called by muse, mutect2, varscan2
- TBXT | c.-75C>T | 5'UTR (SNP) | VAF 44/103 reads (43%) | called by muse, mutect2, varscan2
- TCF4 | c.1638-119C>T | Intron (SNP) | VAF 10/90 reads (11%) | catalogued as rs1406712207, COSV61894888; called by muse, mutect2, varscan2
- TCTEX1D2 | chr3:196318331 del GAACTGGTCGC | 5'Flank (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- TMEM216 | c.*300C>T | 3'UTR (SNP) | VAF 180/392 reads (46%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.-139T>C | 5'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, varscan2
- TWF1P1 | n.1019G>T | RNA (SNP) | VAF 10/239 reads (4%) | called by muse, mutect2
- ZCCHC10 | c.*305A>G | 3'UTR (SNP) | VAF 194/288 reads (67%) | called by muse, mutect2, varscan2
